CCDI case PBBKDM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ba0b1882-dee1-41dc-8a7d-5704a5fe6a86

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,228 days).

Biospecimens (3 samples)
- Sample 0DBW3U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBW4E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DCM0Z: Tissue type: Tumor; Specimen type: Solid Tissue.
